Somatic mutation profile of tumor specimen MMRF_2401_1_PB_CD138pos (aliquot MMRF_2401_1_PB_CD138pos_T3_KHS5U_L12873) from MMRF case MMRF_2401, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.5 years (23,552 days).
Specimen MMRF_2401_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e3f84f0-d2fe-4846-a9b2-6241e50ed47b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2401_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2401_1_PB_CD3pos_C5_KHS5U_L12875; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c084732-b21d-47cf-ae03-7bfb4cdfe62a

The open-access MAF lists 120 somatic variants for this specimen: 51 protein-altering or splice-affecting, 7 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 37, Intron 14, Silent 7, 5'UTR 5, 5'Flank 3, Nonsense Mutation 2, RNA 2, In Frame Del 2, Frame Shift Del 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 27/141 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AR | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.945); catalogued as COSV101017601; called by muse, mutect2, varscan2
- GTSE1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs765217704, COSV101483231; called by muse, varscan2
- IGHV2-70 | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs546960655; called by muse, varscan2
- IGLV3-27 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs761313604; called by muse, mutect2
- IL17C | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54918553; called by mutect2, varscan2
- MNX1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs774909386; called by muse, mutect2, varscan2
- NBPF3 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV59057695; called by muse, mutect2, varscan2
- PCDH9 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1166291287; called by muse, varscan2
- PDP1 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1259886475; called by muse, mutect2, varscan2
- RAI1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV55390494; called by muse, mutect2, varscan2
- SLA2 | c.392_395del p.S131Cfs*77 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs770643107; called by mutect2, pindel
- TOR4A | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV62627054; called by muse, mutect2, varscan2
- ADH1C | c.1021T>C p.F341L | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- BTBD11 | c.2543A>G p.E848G (on ENST00000280758 / NM_001018072.2; = p.E385G on NM_001017523.2) | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CCNB3 | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CEP350 | c.1355C>G p.S452* | Nonsense Mutation (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- CFAP73 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- CIITA | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CKMT1B | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, varscan2
- CRYBG1 | c.2172A>T p.K724N | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DENND4B | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DGKB | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGR1 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, varscan2
- EPHA10 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FBXO42 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD7 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GALR3 | c.884C>G p.S295W | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJA10 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- GRAMD4 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HOXA13 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IGHA1 | c.385del p.L129Cfs*11 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | called by mutect2, pindel, varscan2
- IGHV2-70 | c.246_248del p.S83del | In Frame Del (DEL) | VAF 30/224 reads (13%) | called by pindel, varscan2
- IGHV2-70D | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- IGLV3-27 | c.337A>T p.N113Y | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- INTS8 | c.238A>C p.I80L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1109 | c.9835G>A p.D3279N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LRRC4 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 79/406 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MUC16 | c.19864C>A p.P6622T | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- MUC20 | c.1868G>T p.S623I | Missense Mutation (SNP) | VAF 83/770 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPAP1 | c.2809A>C p.S937R | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP210 | c.4287A>G p.R1429= | Splice Region (SNP) | VAF 9/24 reads (38%) | called by muse, varscan2
- OR2T34 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRPS1L1 | c.458_463del p.K153_W154del | In Frame Del (DEL) | VAF 48/271 reads (18%) | called by mutect2, pindel, varscan2
- PTPDC1 | c.1811T>C p.V604A (on ENST00000375360 / NM_177995.3; = p.V656A on NM_152422.4) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC24A2 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 87/445 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORBS3 | c.1184C>A p.S395Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TDRD9 | c.2510C>A p.S837Y | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TSPAN14 | c.700T>G p.Y234D | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ZNF395 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF620 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ENC1 | c.441C>A p.T147= | Silent (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- EPS8L1 | c.411C>T p.F137= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52381635; called by muse, mutect2, varscan2
- FAM83B | c.765C>T p.L255= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs767086906; called by muse, mutect2, varscan2
- IGHV2-70D | c.354G>A p.R118= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, varscan2
- PGM2 | c.1731G>A p.G577= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- SERPINA11 | c.366C>T p.L122= | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as rs1204702266; called by muse, mutect2, varscan2
- TERT | c.1257C>T p.V419= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs1271171667; called by muse, varscan2
- ABCB10 | c.*367G>A | 3'UTR (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- ABHD18 | c.*379T>G | 3'UTR (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- AC026410.1 | n.1072C>T | RNA (SNP) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- ACP3 | c.*234G>A | 3'UTR (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- ADH1B | c.*732A>G | 3'UTR (SNP) | VAF 33/169 reads (20%) | catalogued as rs1013991964; called by muse, mutect2, varscan2
- ALX3 | c.595-24C>G | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- ATXN1 | c.*5712G>T | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- ATXN7 | c.*1845_*1849del | 3'UTR (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 45/199 reads (23%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BCL9L | c.*2463G>C | 3'UTR (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- BTG1 | c.*891C>T | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- BTG2 | c.*420T>A | 3'UTR (SNP) | VAF 61/135 reads (45%) | called by muse, mutect2, varscan2
- CCDC144B | n.198G>A | RNA (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CDH15 | c.*318G>A | 3'UTR (SNP) | VAF 42/177 reads (24%) | catalogued as rs1345274416; called by muse, mutect2, varscan2
- CLDN23 | c.-17C>A | 5'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- CLIP4 | c.*1873C>G | 3'UTR (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- COPS3 | c.762+348C>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- DENND1A | c.1489-10189T>C | Intron (SNP) | VAF 59/236 reads (25%) | called by muse, mutect2, varscan2
- FCHO1 | c.*89A>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- FCHO1 | c.*90C>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- GADD45B | c.-143C>T | 5'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as rs1319520144; called by muse, varscan2
- GID4 | c.*2209G>A | 3'UTR (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- GLP1R | c.*1164G>A | 3'UTR (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- GNA12 | c.526-29338G>A | Intron (SNP) | VAF 16/82 reads (20%) | catalogued as rs1395207908; called by mutect2, varscan2
- HES2 | c.*1884C>A | 3'UTR (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- HTR1F | c.*280_*281dup | 3'UTR (INS) | VAF 14/56 reads (25%) | catalogued as rs199952254; called by mutect2, varscan2
- ITCH | chr20:34509032 G>A | 3'Flank (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- KCTD20 | c.*3749G>A | 3'UTR (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- LASP1 | c.*1672C>T | 3'UTR (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- LNPK | c.*2440C>T | 3'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- MARCHF3 | c.*2121A>C | 3'UTR (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- MDM1 | c.*384G>A | 3'UTR (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- MMP16 | c.*3994T>C | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by mutect2, varscan2
- MUC19 | chr12:40525404 G>A | 5'Flank (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40525567 G>C | 5'Flank (SNP) | VAF 29/254 reads (11%) | called by muse, varscan2
- NEDD9 | c.460-5719T>A | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- PLAGL2 | c.*3902G>C | 3'UTR (SNP) | VAF 76/337 reads (23%) | called by muse, mutect2, varscan2
- PLAGL2 | c.*2523G>C | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by mutect2, varscan2
- PLXNA2 | c.*2975T>G | 3'UTR (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3418-55G>A | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PNRC1 | c.-88C>T | 5'UTR (SNP) | VAF 80/440 reads (18%) | catalogued as rs1284401396; called by muse, mutect2, varscan2
- PRKACB | c.47-14333C>T | Intron (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.*799G>A | 3'UTR (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- RAB3B | c.*258C>T | 3'UTR (SNP) | VAF 32/138 reads (23%) | catalogued as rs538187538; called by muse, mutect2, varscan2
- RNF144B | c.-150A>T | 5'UTR (SNP) | VAF 15/63 reads (24%) | called by muse, varscan2
- RNF182 | c.*291G>A | 3'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- RPL30 | c.22-37G>A | Intron (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- SCAMP4 | c.-42+43_-42+60delinsG | Intron (DEL) | VAF 21/137 reads (15%) | called by pindel, varscan2*
- SDR42E1 | c.69-187A>G | Intron (SNP) | VAF 57/239 reads (24%) | called by muse, mutect2, varscan2
- SEMA5B | c.-38-14727G>A | Intron (SNP) | VAF 42/340 reads (12%) | called by muse, mutect2, varscan2
- SGIP1 | c.*1092T>A | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- SH3D19 | c.*896A>T | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- SLK | c.*2586T>A | 3'UTR (SNP) | VAF 30/164 reads (18%) | called by muse, mutect2, varscan2
- SNRPB2 | c.*514G>A | 3'UTR (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- SOX1 | c.*437T>A | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- SRSF11 | c.1023-112A>G | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- TERB2 | c.*381T>C | 3'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- TNIP1 | c.847-63C>T | Intron (SNP) | VAF 22/104 reads (21%) | catalogued as rs574324382; called by muse, mutect2, varscan2
- USP44 | c.*212T>A | 3'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, varscan2
- ZBP1 | c.-84C>T | 5'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as rs931269334; called by muse, mutect2, varscan2
- ZNF493 | c.-132+8049C>T | Intron (SNP) | VAF 44/188 reads (23%) | called by muse, varscan2
- ZNF738 | c.*730C>G | 3'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
